Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AD3B, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AD3B-TTP1-A (Primary Tumor).

[page 1 of 15]
Patient Name: [REDACTED] Accession #: [REDACTED]
DOB: [REDACTED] Client: [REDACTED]
Gender: F Loc: [REDACTED] Collected: [REDACTED] +0
Med Rec #: [REDACTED] Account: [REDACTED] Received: [REDACTED] +1
Physician(s): [REDACTED] Reported: [REDACTED] +2

Specimen Source:

A: Right breast core biopsy, 10:00
B: Right breast core biopsy, 9:00

Date Ordered: [REDACTED] +17
Status: Signed Out

Addendum Diagnosis

Tissue submitted: Right breast, 10:00 (invasive carcinoma) Block # tested: A

**Hormone Receptor and Oncogene Analysis
Immunohistochemical Technique**

Antibody	Tumor Staining	Stain Intensity/Quality	Result
ER clone 1D5	3+ (5% of cells)	Heterogeneous	Positive
PR clone PgR636	2+ (5% of cells)	Heterogeneous	Positive
Her-2	2+ (< 10% of cells)	Predominantly 1+	Negative

NOTES

ER/PR Reference Range: No staining = negative and staining > or equal to 1% = positive. Her 2 is scored 0 to 3+ and 2+ or 3+ are considered overexpression. Recent articles suggest any nuclear staining may be significant. % tumor staining is determined in immunoreactive areas only. The clinical significance of ER/PR staining intensity and quality is not entirely clear at this time. It is possible that tumors with low intensity and/or heterogeneous staining may have different biologic behavior than tumors demonstrating strong homogeneous staining. Despite appropriate positive and negative controls and observation for internal control staining, false-negative results are possible. For estrogen and progesterone receptors, only staining of tumor cell nuclei is considered positive. For Her 2, only membrane staining is considered positive.

NOTE: The above test performed on formalin fixed, paraffin embedded sections using the Envision+ kit and DAB+ Chromagen was developed and its characteristics determined by the laboratory at [REDACTED]. It has been cleared or approved by the US Food & Drug Administration. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Addendum Comment

This testing was performed at the request of [REDACTED]

[page 2 of 15]
SURGICAL PATHOLOGY CONSULTATION REPORT

Patient Name: [REDACTED] Accession No: [REDACTED]
DOB: [REDACTED] Client: [REDACTED]
Gender: F Loc: [REDACTED]
Med Rec #: [REDACTED] Account: [REDACTED]
Physician: [REDACTED] Collected: [REDACTED] +0
Received: [REDACTED] +1
Reported: [REDACTED] +2

Specimen Source:

A: Right breast core biopsy, 10:00
B: Right breast core biopsy, 9:00

FINAL DIAGNOSIS

- A. Breast, right, at 10:00-#1, core biopsies:
Invasive ductal carcinoma (see comment).
Associated microcalcifications.
- B. Breast, right, at 9:00-#2, core biopsies:
Invasive ductal carcinoma.
Fibrocystic changes with ductal hyperplasia of usual type.

Comments

These results were called to the [REDACTED] on [REDACTED] Special stains for estrogen receptor, progesterone receptor, and Her-2/neu are deferred to final resection.

Clinical History

57-y.o. female with a suspicious mass, right breast, at 10:00 and probable satellite nodule, right breast at 9:00. Half-sister died of breast cancer. Ph/fax result

Gross

- A. "Right breast 10:00, #1": Three fibrofatty tissue cores 1.2 to 1.4 cm. Inked ES, 1C.
B. "Right breast 9:00, #2": Three fibrofatty tissue cores 0.9 to 1.3 cm. Inked. ES, 1C.

Microscopic

[page 3 of 15]
A. Sections show breast stromal tissue with infiltrating, highly-atypical groups of epithelial cells. A small proportion of the atypical cells show gland formation and associated microcalcifications. No definitive in-situ component is identified. No lymphovascular invasion is identified. QA-CONF

B. Sections show infiltrating tumor cells which appear morphologically similar to those described in specimen A. Background glands show proliferative fibrocystic changes. No lymphovascular invasion is identified.

[page 4 of 15]
CYTOPATHOLOGY CONSULTATION REPORT

Patient Name:		Client:		Accession No:	
DOB:		Loc:		Collected:	+13
Gender:	F	Account:		Received:	+14
Med Rec #:				Reported:	+15
Physician:					

Specimen Source:

L1 Bone biopsy, Fine Needle Aspiration

FINAL DIAGNOSIS

Spine, L1 bone, FNA for cytology and cell block:

Positive for metastatic adenocarcinoma (see comment).

Comments

This tumor is morphologically similar to the patient's recently diagnosed invasive breast ductal carcinoma (see [redacted]).

Clinical History

Multiple bone lesions. Breast CA dx [redacted] +0

Gross

L1 bone, FNA (2 passes): 17 ml pink fluid (2 Pap, 2 DQ, cell block).

Intraoperative Consultation

A. L1 bone: Fine needle aspiration (2 passes).
Diagnosis: 1st pass: Blood; no epithelial cells; 2nd pass: Multiple groups of atypical epithelial cells; adequate.
Reported to: [redacted]

Microscopic

The preparation shows multiple large groups of atypical epithelioid cells which are cohesive and demonstrate vague glandular differentiation. The tumor cells show large size, moderate cytoplasm, and moderately pleomorphic nuclei with mitotic figures. [redacted]

[page 5 of 15]
Patient
MRN: (

Anatomic Pathology Results Posted by Result Date (Reverse Chronological Order):

Please review all results carefully. This report does not flag clinically significant results.

Result Date/Time: [REDACTED]

FINAL REPORT

+13

CYTOPATHOLOGY CONSULTATION REPORT

Patient Name: [REDACTED]

Accession No: [REDACTED]

DOB: [REDACTED]

Gender: F

Med Rec #: [REDACTED]

Client: [REDACTED]

Loc: RAI [REDACTED]

Account: [REDACTED]

Collected: [REDACTED] +13

Received: [REDACTED] +14

Reported: [REDACTED] +15

Physician: [REDACTED]

Specimen Source:

L1 Bone biopsy, Fine Needle Aspiration

FINAL DIAGNOSIS

Spine, L1 bone, FNA for cytology and cell block:

Positive for metastatic adenocarcinoma (see comment).

Comments

This tumor is morphologically similar to the patient's recently diagnosed invasive breast ductal carcinoma (see [REDACTED]).

Gross

L1 bone, FNA (2 passes): 17 ml pink fluid (2 Pap, 2 DQ, cell block).

Intraoperative Consultation

A. L1 bone: Fine needle aspiration (2 passes).

Diagnosis: 1st pass: Blood; no epithelial cells; 2nd pass:

Multiple groups of atypical epithelial cells; adequate.

Reported to: [REDACTED]

Microscopic

[page 6 of 15]
The preparation shows multiple large groups of atypical epithelioid cells which are cohesive and demonstrate vague glandular differentiation. The tumor cells show large size, moderate cytoplasm, and moderately pleomorphic nuclei with mitotic figures. QA-Conf.

Result Date/Time: [REDACTED]

FINAL REPORT

+0

SURGICAL PATHOLOGY CONSULTATION REPORT

Patient Name: [REDACTED]

Accession No: [REDACTED]

DOB: [REDACTED]

Client: [REDACTED]

Imaging: [REDACTED]

Gender: F

Loc: [REDACTED]

Med Rec #: [REDACTED]

+0

Account: [REDACTED]

Collected: [REDACTED]

+1

Received: [REDACTED]

Reported: [REDACTED]

+2

Physician: [REDACTED]

Specimen Source:

A: Right breast core biopsy, 10:00

B: Right breast core biopsy, 9:00

FINAL DIAGNOSIS

A. Breast, right, at 10:00-#1, core biopsies:

Invasive ductal carcinoma (see comment).

Associated microcalcifications.

B. Breast, right, at 9:00-#2, core biopsies:

Invasive ductal carcinoma.

Fibrocystic changes with ductal hyperplasia of usual type.

Comments

+2

These results were called to the [REDACTED] on [REDACTED] by [REDACTED].
Special stains for estrogen receptor, progesterone receptor, and Her-2/neu are deferred to final resection.

Clinical History

[REDACTED]-y.o. female with a suspicious mass, right breast, at 10:00 and probable satellite nodule, right breast at 9:00. Half-sister died of breast cancer.
Ph/fax result

Gross

A. "Right breast 10:00, #1": Three fibrofatty tissue cores 1.2 to 1.4

[page 7 of 15]
cm. Inked ES, 1C.

B. "Right breast 9:00, #2": Three fibrofatty tissue cores 0.9 to 1.3

cm. Inked. ES, 1C.

Microscopic

A. Sections show breast stromal tissue with infiltrating, highly-atypical groups of epithelial cells. A small proportion of the atypical cells show gland formation and associated microcalcifications. No definitive in-situ component is identified. No lymphovascular invasion is identified.

B. Sections show infiltrating tumor cells which appear morphologically similar to those described in specimen A. Background glands show proliferative fibrocystic changes. No lymphovascular invasion is identified.

+17

Procedures/Addenda

ADDENDUM Date Ordered: Status: Signed Out

Date Complete:

Date Reported: +17

Addendum Diagnosis

Tissue submitted: Right breast, 10:00 (invasive carcinoma)

Block # tested: A

Hormone Receptor and Oncogene Analysis Immunohistochemical Technique

Antibody	Tumor Staining	Stain Intensity/Quality
Result		
ER clone 1D5	3+ (5% of cells)	Heterogeneous
Positive		
PR clone PgR636	2+ (5% of cells)	Heterogeneous
Positive		
Her-2	2+ (< 10% of cells)	Predominantly 1+
Negative		

NOTES:

ER/PR Reference Range: No staining = negative, and staining > or equal to 1% = positive. Her-2 is scored 0 to 3+, and 2+ or 3+ are considered overexpression. Recent articles suggest any nuclear staining may be significant. % tumor staining is determined in immunoreactive areas only. The clinical significance of ER/PR staining intensity and quality is not entirely clear at this time. It is possible that tumors with low intensity and/or heterogeneous staining may have different biologic behavior than tumors demonstrating strong homogeneous staining. Despite appropriate positive and negative controls and observation for internal control staining, false-negative results are possible. For estrogen and progesterone receptors, only staining of tumor cell nuclei is considered positive. For Her-2, only membrane staining is considered positive.

NOTE: The above test performed on formalin-fixed, paraffin-embedded sections, using the Envision+ kit and DAB+ Chromagen, was developed and its characteristics determined by the laboratory at

It has been cleared or approved by the US Food & Drug Administration. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Addendum Comment

This testing was performed at the request of
Electronically signed by

[page 8 of 15]
Patient:
DOB:
Site:
Ref. Prov
Add. Prov

EMPI:
PT:
Exam:

Visit/Acet:
MRN:
Room/Bed: /

Baseline

EXAM DATE:

Contrast: 100cc Isovue 300 SD/0cc discarded

+7

PROCEDURE: CT OF THE CHEST WITH INTRAVENOUS CONTRAST

COMPARISON: US, US ABDOMEN, LIMITED.
BC, PC MAMMO DIGIT DIAG BIL W/ CAD.

+7

-5

INDICATIONS: Worsening substernal pain for two months. New diagnosis of breast cancer.

TECHNIQUE: CT scan of the chest was performed with non-ionic intravenous contrast.

FINDINGS:

NECK BASE: Normal.
LUNGS: Numerous bilateral pulmonary nodules are evident compatible with metastatic disease.
VASCULATURE: Normal.
MEDIASTINUM/HILA: No enlarged adenopathy is evident. There is abnormal thickening of the distal esophagus. This could be inflammatory, but an esophageal mass is not excluded.
CARDIAC: Normal.
PLEURA: Normal.
CHEST WALL/AXILLA: A large right breast mass is evident. Multiple small left-sided breast masses are noted as well. No enlarged axillary adenopathy is observed.
LIMITED ABDOMEN: There is fatty infiltration of the liver. Additionally, there is some heterogeneity of the liver parenchyma. While this could simply be a heterogeneous distribution of fat, the possibility of subtle metastatic lesions cannot be entirely excluded.
BONES: Multiple lytic bony lesions are evident, most prominent in the upper thoracic spine involving the third and fourth vertebral bodies and posterior elements. Abnormal paraspinous soft tissue thickening is evident. Potential for spinal canal stenosis should be evaluated with MRI as the soft tissue component is difficult to see on this exam. There are also destructive bony lesions at T11, L1, and L2. Destructive changes evident in the medial aspect of the left scapula.
OTHER: None.

CONCLUSION: Exam demonstrates findings of disseminated neoplasm involving bone and lungs. Multiple spinal lesions put patient at risk for insufficiency fracture. Lesions at T4 and at L1 have the greatest potential for soft tissue incursion on the spinal canal. Screening spine MRI is strongly suggested to evaluate tumor burden.

There are bilateral breast masses as described previously.

Multiple pulmonary nodules are evident compatible with metastases.

There is abnormal thickening of the distal esophagus which could be inflammatory, but unfortunately this may represent a second primary tumor.

[page 9 of 15]
Continued Report - Page 2 of 2

Patient:
DOB:
Site:
Ref. Prov:
Add. Prov:

EMPI:
PT:
Exam:

Visit/Acct:
MRN:
Room/Bed:

EXAM DATE:

Contrast: 100cc Isovue 300 SD/0cc discarded

+7 There is diffuse fatty infiltration of the liver. Unfortunately, there is heterogeneity of the liver parenchyma which is indeterminate. Subtle liver masses cannot be entirely excluded.

[page 10 of 15]
Patient:

DOB:

Site:

Ref. Prov

Add. Prov

Pt:

m:

Visit/Acct:

MRN:

Room/Bed:

EXAM DATE:

Contrast:

+7

PROCEDURE: ABDOMINAL ULTRASOUND, LIMITED

INDICATIONS: Substernal chest pain and right upper quadrant abdominal pain for two months.

COMPARISON: None.

TECHNIQUE: Sonographic images of the right upper quadrant were obtained.

FINDINGS:

LIVER: Borderline hepatic enlargement. Liver is echogenic and measures 18.4 cm in length.
GALLBLADDER: No stones, wall thickening, or pericholecystic fluid. Negative Murphy's sign.
CHD/CBD: Extrahepatic biliary duct is normal in caliber, measuring 5mm.
PANCREAS: Visualized portions appear normal.
RIGHT KIDNEY: Within normal limits. 10.4 cm in length.
OTHER: None.

CONCLUSION: Enlarged echogenic liver is compatible with fatty infiltration.

Normal appearance of the gallbladder and common duct.

[page 11 of 15]
CT Abdomen w Contrast

5

* Final Report *

*** Final Report ***

CT ABDOMEN WITH CONTRAST

PROCEDURE: CT CHEST AND ABDOMEN WITH INTRAVENOUS CONTRAST

INDICATIONS: Metastatic breast cancer. Evaluate response to chemotherapy.

+140

Best Response

COMPARISON: [REDACTED] CT, CT CHEST AND ABDOMEN WITH CON, [REDACTED]

TECHNIQUE: CT of the chest and abdomen obtained following IV administration of contrast.

FINDINGS:

NECK BASE: Normal.

LUNGS: Interval retraction of radiation pneumonitis and fibrosis in the left upper lobe periphery. Several tiny nodules in the right lung are less conspicuous and smaller than prior study, these could be metastases responding to therapy or inflammatory nodules which are resolving.

MEDIASTINUM: Normal.

CARDIAC: Normal.

PLEURA/CHEST WALL: Interval decrease in size of right breast mass currently measuring 2.6 x 2.1 cm, previously measuring 4.1 x 1.9 cm. No axillary adenopathy.

LIVER: Diffuse fatty infiltration of the liver. No focal liver lesion.

BILIARY: Normal.

PANCREAS: Normal.

SPLEEN: Normal.

KIDNEYS: Normal.

ADRENALS: Normal.

AORTA/VASCULAR: Normal.

RETROPERITONEUM: Normal.

BOWEL/MESENTERY: Visualized portions appear normal.

ABDOMINAL WALL: Normal.

BONES: Interval increased sclerosis of multiple bone lesions consistent with treatment response. Interval increase in compression and mild retropulsion of bone at the T3 pathologic compression fracture. Multiple sclerotic bone lesions are more evident now because they have become sclerotic.

CONCLUSION: Interval increased sclerosis in numerous vertebral spine lesions most consistent with treatment response to osseous metastatic disease. The pathologic compression fracture of T3 has worsened.

[page 12 of 15]
CT Abdomen w Contrast

* Final Report *

Several tiny right lung nodules appear slightly smaller than prior, these could be metastases responding to therapy or inflammatory nodules. They are not specific.

Smaller right breast mass.

No new sites of metastatic disease.

Retracting radiation pneumonitis/fibrosis left upper lobe.

Type: CT Abdomen w Contrast
Date: [REDACTED] +387
Status: Auth (Verified)
Title: CT ABDOMEN WITH CONTRAST
By: [REDACTED]
Verified By: [REDACTED]
Encounter info: [REDACTED]
Contributor system: [REDACTED]

Printed by:
Printed on:

Page 2 of 2
(End of Report)

[page 13 of 15]
CT Chest/Abd/Pelvis w Contrast (BIA)

* Final Report *

* Final Report *

Reason For Exam
breast ca, restaging

REPORT

PROCEDURE: CT CHEST, ABDOMEN, AND PELVIS WITH CONTRAST

COMPARISON: [REDACTED] CT, CT PNL CHEST/ABD/PELVIS WITH
CONTRAST, [REDACTED] NM, NM BONE
SCAN COMP, [REDACTED] +2002

INDICATIONS: Breast cancer. Restaging

PQRS QUALITY INFORMATION:

EXAM COUNT: 1 CT exams and 0 NM Myocardial Perfusion exams in past 12 months.

DATA AVAILABILITY: Dicom format image data is available to non-affiliated external entities on secure, media free, reciprocally searchable basis for 12 month period of time after the study.

DATA SEARCH: A search was conducted for prior patient CT exams performed at an external facility within 12 months prior to the imaging study being performed, and is available through a secure, authorized, media free, shared archive.

CT DOSE REGISTRY: CT study data has been reported to a CT Radiation Dose Index Registry containing all minimum necessary data elements.

Total Dose Length Product (DLP in mGy-cm):

TECHNIQUE: CT scan of the chest, abdomen, and pelvis was performed with non-ionic intravenous contrast.

FINDINGS:

NECK BASE: Normal.
LUNGS: Stable 3 mm nodule in the right middle lobe image 62. Stable treatment changes in the left upper lung.
AORTA/VASCULAR: Normal.
HILA/MEDIASTINUM: Small hiatal hernia.
CARDIAC: Normal.
PLEURA: Normal.
CHEST WALL/AXILLA: Stable 1.9 x 2.1 cm mass in the right breast on image 53. Stable 1.3 cm mass in the left breast on image 56.
LIVER: Diffuse hepatic steatosis.
BILIARY: Normal.
PANCREAS: Normal.
SPLEEN: Normal.

Printed by: [REDACTED]
Printed on: [REDACTED]

Page 1 of 3
(Continued)

[page 14 of 15]
CT Chest/Abd/Pelvis w Contrast (BIA)

* Final Report *

KIDNEYS: Scarring in the upper poles of the kidneys bilaterally.
ADRENALS: Normal.
RETROPERITONEUM: Normal.
BOWEL/MESENTERY: Normal.
ABDOMINAL WALL: Normal.
PELVIC ORGANS: Normal.
BONES: Osseous metastatic disease again seen within the spine and pelvis. Moderate to severe compression deformity of the sclerotic T3 vertebral body is unchanged. Sclerosis and destruction of the L1 vertebral body is not significantly changed. Endplate sclerosis again seen at L2-L3 with a large ossific fragment seen within the spinal canal at this level resulting in a severe spinal canal stenosis, unchanged. Degenerative changes seen in the visualized cervical spine. Posterior disc osteophyte complex and facet hypertrophy at L3-4 resulting in severe spinal canal stenosis. Posterior disc bulge and severe facet hypertrophy at L4-5 resulting in moderate spinal canal stenosis.
OTHER: Negative.

CONCLUSION: Stable osseous metastatic disease. Large extradural calcific, ossified lesion in L3 resulting in significant spinal canal stenosis. There is also severe spinal canal stenosis at L3-4. Stable pathologic fracture of L1 and T2.

Stable small bilateral breast masses.

Signature Line

Type: CT Chest/Abd/Pelvis w Contrast (BIA)
Date:

+2179

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 15 of 15]
CT Chest/Abd/Pelvis w Contrast (BIA)

* Final Report *

Status:

Title:

By:

Verified By:

Encounter info:

Printed by:

Printed on:

Source: NCI Genomic Data Commons file e6fe614f-7fb4-4d6c-85c1-311ec25af938 (ER0241 ER-AD3B Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).